Somatic mutation profile of tumor specimen 0DI201 from CCDI case PBBVEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 9.2 years (3,354 days).
Specimen 0DI201: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8d7d5a2-a36c-4532-bc86-46eefbef990d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI1JU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec636246-866c-44bf-b153-0b5731837662

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PZP | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 128/446 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54359907; called by muse, varscan2
- TRIM9 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445755156; called by muse, mutect2
- DZIP3 | c.2972G>T p.G991V | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LRRCC1 | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 122/545 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NPAP1 | c.2467A>G p.S823G | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2
- PIH1D1 | c.338-4G>A | Splice Region (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- SCN7A | c.3987A>C p.L1329= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, varscan2
- SLC41A2 | c.24T>C p.S8= | Silent (SNP) | VAF 117/464 reads (25%) | called by muse, mutect2, varscan2
- ZBTB9 | c.162G>A p.V54= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs759435678; called by muse, mutect2, varscan2
- ARHGEF10L | c.*3C>A | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by mutect2, varscan2
- SPHK1 | c.374+41del | Intron (DEL) | VAF 4/34 reads (12%) | called by mutect2, varscan2
